Somatic mutation profile of tumor specimen TCGA-P6-A5OG-01A (aliquot TCGA-P6-A5OG-01A-22D-A29I-10) from TCGA case TCGA-P6-A5OG, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 45.6 years (16,659 days).
Specimen TCGA-P6-A5OG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab256d6a-7fc0-4c90-86d8-417ec7fde236.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P6-A5OG-10A (Blood Derived Normal), aliquot TCGA-P6-A5OG-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8341f297-f6d2-4178-8dcf-985be1e0dbcd

The open-access MAF lists 251 somatic variants for this specimen: 182 protein-altering or splice-affecting, 64 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 151, Silent 64, Nonsense Mutation 13, Splice Site 8, Frame Shift Del 5, RNA 3, Frame Shift Ins 2, Splice Region 2, Intron 1, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 23/111 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCA13 | c.9406G>T p.E3136* | Nonsense Mutation (SNP) | VAF 7/116 reads (6%) | catalogued as COSV71289134; called by muse, mutect2
- ACVRL1 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM062400, COSV101188034, COSV66361188; called by mutect2, varscan2
- ARGFX | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.55); catalogued as rs144775023; called by muse, mutect2, varscan2
- ARID1A | c.1624C>T p.Q542* | Nonsense Mutation (SNP) | VAF 17/116 reads (15%) | catalogued as COSV61372218; called by muse, mutect2, varscan2
- ARRDC3 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 28/155 reads (18%) | catalogued as rs762978398, COSV99475182; called by muse, mutect2, varscan2
- CCDC54 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as rs868113315; called by muse, mutect2
- CD1C | c.931G>T p.V311L | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV63805590, COSV63807420; called by muse, mutect2, varscan2
- CHMP3 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.324); catalogued as rs770673887; called by muse, mutect2, varscan2
- CHST1 | c.1172A>G p.E391G | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs747255778; called by muse, varscan2
- CHST5 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs752681577, COSV60337403, COSV60338096; called by muse, mutect2, varscan2
- CYFIP2 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as rs1377123656, COSV59027617; called by muse, mutect2
- DACT1 | c.2119G>T p.A707S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs755263046, COSV60019157; called by muse, mutect2, varscan2
- DAO | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs150448350; called by muse, mutect2, varscan2
- DMXL1 | c.2542G>T p.G848C | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as rs757274585; called by muse, mutect2
- DNAH5 | c.9193C>A p.P3065T | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV54242797; called by muse, mutect2, varscan2
- DSG4 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100355344; called by muse, varscan2
- DST | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs748063375; called by muse, mutect2, varscan2
- EHMT2 | c.2500G>T p.A834S | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.949); catalogued as rs1192060899; called by muse, mutect2, varscan2
- FAM47A | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.181); catalogued as rs753875155, COSV60498289, COSV60499246; called by muse, mutect2, varscan2
- FBXO11 | c.2678G>A p.G893E (on ENST00000403359 / NM_001190274.2; = p.G809E on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99316376; called by muse, mutect2, varscan2
- FGF3 | c.644A>T p.Q215L | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV61926322; called by muse, mutect2, varscan2
- FNDC1 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51938501; called by muse, mutect2, varscan2
- FOXS1 | c.132del p.Y45Tfs*120 | Frame Shift Del (DEL) | VAF 46/141 reads (33%) | catalogued as COSV54066884; called by mutect2, pindel*, varscan2*
- FREM1 | c.1450C>A p.H484N | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV66531145; called by muse, mutect2, varscan2
- GIPC3 | c.892C>T p.R298* (on ENST00000644946; = p.P293= on NM_133261.3) | Nonsense Mutation (SNP) | VAF 39/206 reads (19%) | catalogued as rs1214059089; called by muse, mutect2, varscan2
- GOLGA4 | c.4452G>T p.L1484F | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs898840190; called by muse, mutect2, varscan2
- GPAM | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV62081571; called by muse, mutect2, varscan2
- GPR149 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs199967865, COSV67667010; called by muse, mutect2, varscan2
- GRM3 | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64469393; called by muse, mutect2
- H2AC6 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.786); catalogued as rs769189449; called by muse, mutect2, varscan2
- HNRNPF | c.649A>G p.R217G | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100563025; called by muse, mutect2, varscan2
- HSPG2 | c.8608C>T p.R2870W | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs764778166; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ICE2 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV55030888; called by muse, mutect2, varscan2
- IGSF21 | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52135787; called by muse, mutect2
- KY | c.1784T>A p.V595D | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV101415015; called by muse, mutect2
- LRFN5 | c.1789G>C p.E597Q | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as COSV53250975; called by muse, mutect2, varscan2
- MAN2A1 | c.3364G>A p.G1122S | Missense Mutation (SNP) | VAF 65/388 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.013); catalogued as rs754873050; called by muse, mutect2, varscan2
- MAST4 | c.1035G>C p.R345S (on ENST00000403625 / NM_001164664.2; = p.R156S on NM_015183.3) | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55126303; called by muse, mutect2
- MME | c.2076+1G>T p.X692_splice | Splice Site (SNP) | VAF 32/250 reads (13%) | catalogued as COSV64705915; called by muse, mutect2, varscan2
- MPPED2 | c.734C>A p.P245H | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100813111, COSV63901358; called by muse, mutect2, varscan2
- MUC17 | c.6101T>C p.I2034T | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs184841146; called by muse, mutect2, varscan2
- MUC7 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59218615; called by muse, mutect2, varscan2
- OR14C36 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58601030; called by muse, mutect2, varscan2
- OR2Y1 | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as COSV57138065; called by muse, mutect2, varscan2
- OSTF1 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 17/96 reads (18%) | catalogued as rs1383313076; called by muse, mutect2, varscan2
- PADI2 | c.585del p.A196Pfs*5 | Frame Shift Del (DEL) | VAF 19/136 reads (14%) | catalogued as COSV100970998, COSV64945612; called by mutect2, pindel, varscan2
- PCDH10 | c.2073C>G p.S691R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.048); catalogued as COSV99994584; called by muse, mutect2
- PCDHA7 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 46/373 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs558922738, COSV100971907; called by muse, mutect2, varscan2
- PCDHB9 | c.1955G>T p.R652L | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs782383850, COSV53379247; called by muse, mutect2
- PPFIA4 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs780401326, COSV55323599; called by muse, mutect2, varscan2
- PRAMEF20 | c.375A>C p.L125F | Missense Mutation (SNP) | VAF 52/305 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs1168340702; called by muse, mutect2, varscan2
- RBM27 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1318366493; called by muse, varscan2
- REG3A | c.150C>A p.H50Q | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV59409112; called by muse, mutect2, varscan2
- RIMS2 | c.2112G>T p.M704I (on ENST00000666250 / NM_001348490.2; = p.M512I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51679856; called by muse, mutect2, varscan2
- RMDN1 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 20/101 reads (20%) | catalogued as COSV68830633; called by muse, mutect2, varscan2
- ROR1 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV64284430; called by muse, mutect2, varscan2
- RPAP3 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs371796000; called by muse, mutect2, varscan2
- SCARA3 | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757420816, COSV57270347; called by muse, mutect2
- SLC2A3 | c.1069-1G>T p.X357_splice | Splice Site (SNP) | VAF 29/156 reads (19%) | catalogued as COSV50000635, COSV50001803; called by muse, mutect2, varscan2
- SPTA1 | c.6627G>T p.M2209I | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as COSV100935470, COSV63753592; called by muse, mutect2, varscan2
- SPTA1 | c.4296G>T p.L1432F | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63751732, COSV63753642; called by muse, mutect2
- STS | c.1322G>T p.C441F | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM920655; called by muse, mutect2, varscan2
- TGM6 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs758999541, COSV52482088, COSV99171679; called by muse, mutect2, varscan2
- TIAM1 | c.1309G>C p.A437P | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54548378; called by muse, mutect2, varscan2
- TRIOBP | c.2129C>T p.S710F | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as COSV100730793; called by muse, mutect2, varscan2
- TTN | c.57493G>A p.D19165N (on ENST00000591111; = p.D11741N on NM_003319.4) | Missense Mutation (SNP) | VAF 23/137 reads (17%) | PolyPhen possibly damaging (0.747); catalogued as COSV100598404; called by muse, mutect2, varscan2
- USP24 | c.4952A>G p.N1651S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.715); catalogued as rs745333534; called by muse, mutect2, varscan2
- YWHAQ | c.412C>G p.R138G | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); catalogued as COSV99430777, COSV99430926; called by mutect2, varscan2
- ZC3H13 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.257); catalogued as COSV54465834; called by muse, mutect2, varscan2
- A2ML1 | c.1681C>T p.Q561* | Nonsense Mutation (SNP) | VAF 32/176 reads (18%) | called by muse, mutect2, varscan2
- ACTG1 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS16 | c.1874G>T p.C625F | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADAMTS17 | c.2000T>A p.V667E | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS19 | c.830G>C p.R277P | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.935); called by muse, mutect2
- ADSL | c.1087G>T p.V363F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- APLNR | c.37del p.A13Qfs*64 | Frame Shift Del (DEL) | VAF 40/125 reads (32%) | called by mutect2, pindel, varscan2
- APOB | c.8902C>A p.L2968I | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); called by muse, varscan2
- ARHGEF40 | c.3721C>T p.Q1241* | Nonsense Mutation (SNP) | VAF 34/129 reads (26%) | called by muse, mutect2, varscan2
- ARL5B | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.937); called by muse, mutect2
- ATP2C2 | c.1141A>T p.T381S | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP8B2 | c.866T>C p.M289T (on ENST00000672630; = p.M256T on NM_001005855.2) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ATP8B2 | c.2519C>G p.A840G (on ENST00000672630; = p.A807G on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ATP8B2 | c.3379G>T p.D1127Y (on ENST00000672630; = p.D1094Y on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- BICD1 | c.546G>T p.L182F | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C22orf42 | c.258G>A p.W86* | Nonsense Mutation (SNP) | VAF 33/165 reads (20%) | called by muse, mutect2, varscan2
- C3orf20 | c.1273A>G p.T425A | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1S | c.3526-2A>T p.X1176_splice | Splice Site (SNP) | VAF 28/233 reads (12%) | called by muse, mutect2, varscan2
- CERS3 | c.5T>A p.F2Y | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- COL7A1 | c.1381del p.V461Yfs*6 | Frame Shift Del (DEL) | VAF 42/236 reads (18%) | called by mutect2, pindel, varscan2
- CPN1 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by muse, mutect2
- CRISPLD1 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CROT | c.1063-1G>T p.X355_splice | Splice Site (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- CSNK1G1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CST1 | c.426G>C p.*142Yext*80 | Nonstop Mutation (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- CTSC | c.890-2A>G p.X297_splice | Splice Site (SNP) | VAF 47/105 reads (45%) | called by muse, mutect2, varscan2
- DAB2 | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DES | c.1245-1G>A p.X415_splice | Splice Site (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- DOCK2 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- DSG1 | c.3007C>G p.L1003V | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ECPAS | c.3801C>G p.L1267= | Splice Region (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- EPRS1 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ERICH1 | c.1234C>G p.P412A | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- FAT3 | c.4030C>A p.R1344S | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- FAT3 | c.8011A>G p.N2671D | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); called by muse, varscan2
- FLT3 | c.1033G>T p.V345L | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FREM2 | c.4228T>A p.F1410I | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSTL5 | c.80G>C p.G27A | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- GATA4 | c.1031G>T p.S344I | Missense Mutation (SNP) | VAF 96/306 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- GFRA1 | c.511A>T p.R171W | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPT | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HCN1 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2
- HFM1 | c.4272G>A p.M1424I | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- HRG | c.1189C>A p.H397N | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- IGHA1 | c.507C>A p.S169R | Missense Mutation (SNP) | VAF 72/308 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- IGHV1OR21-1 | c.52C>A p.Q18K | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- IGKV5-2 | c.256G>T p.G86W | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGSF21 | c.1115dup p.E373Gfs*19 | Frame Shift Ins (INS) | VAF 23/131 reads (18%) | called by mutect2, pindel, varscan2
- IGSF9B | c.3085C>T p.Q1029* | Nonsense Mutation (SNP) | VAF 34/228 reads (15%) | called by muse, mutect2, varscan2
- IL20RB | c.877G>T p.D293Y | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- IL20RB | c.878A>C p.D293A | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ITIH1 | c.559G>T p.V187L | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- KPNA5 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- LONRF3 | c.2137G>T p.G713C (on ENST00000371628 / NM_001031855.3; = p.G672C on NM_024778.5) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LONRF3 | c.2138G>T p.G713V (on ENST00000371628 / NM_001031855.3; = p.G672V on NM_024778.5) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1 | c.493A>C p.T165P | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- LRRC14B | c.761C>A p.P254H | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRK1 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- MACF1 | c.19335G>T p.Q6445H (on ENST00000372915; = p.Q4490H on NM_012090.5) | Missense Mutation (SNP) | VAF 31/166 reads (19%) | called by muse, mutect2, varscan2
- MAMLD1 | c.709A>T p.K237* | Nonsense Mutation (SNP) | VAF 36/157 reads (23%) | called by muse, mutect2, varscan2
- MANEAL | c.387G>T p.M129I | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- MFSD6L | c.382G>T p.V128L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- MROH9 | c.1385A>T p.Q462L | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- MRPS9 | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- NES | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- NPR3 | c.1171C>A p.Q391K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.238); called by muse, mutect2
- NR4A1 | c.1004A>G p.E335G | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- NSD1 | c.7078A>T p.R2360W | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- OR2G3 | c.263C>A p.P88Q | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- OR8A1 | c.62C>A p.A21E | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR9Q2 | c.18C>A p.Y6* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2
- PAPPA | c.1217G>T p.R406L | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PCDHA11 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- PCDHGA1 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2
- PLEKHA6 | c.84_100del p.E29Gfs*41 | Frame Shift Del (DEL) | VAF 14/144 reads (10%) | called by mutect2, pindel
- PPP2R3A | c.146A>T p.H49L | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRR16 | c.449dup p.N150Kfs*15 (on ENST00000407149 / NM_001300783.2; = p.N127Kfs*15 on NM_016644.2) | Frame Shift Ins (INS) | VAF 13/58 reads (22%) | called by mutect2, pindel, varscan2
- PRR30 | c.914G>A p.G305D | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- PTER | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PTGDR2 | c.935T>A p.L312Q | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- RALGPS2 | c.105G>C p.K35N | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RALYL | c.233G>T p.R78I | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- RBM45 | c.523G>C p.A175P | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SBNO2 | c.2267G>T p.R756L | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- SHROOM3 | c.5657G>T p.G1886V | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- SLF1 | c.3163A>G p.M1055V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPARCL1 | c.547C>A p.Q183K | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SPATA31E1 | c.849C>A p.N283K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.295); called by mutect2, varscan2
- SPATA31E1 | c.1568C>A p.T523N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SPG7 | c.1145G>T p.R382L (on ENST00000268704; = p.R389L on NM_003119.4) | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPOCK2 | c.968A>T p.Q323L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SSX6P | n.344T>C | Splice Region (SNP) | VAF 89/409 reads (22%) | called by muse, mutect2, varscan2
- ST8SIA6 | c.1118C>A p.P373H | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUCNR1 | c.42G>T p.W14C | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SWT1 | c.1972+1G>T p.X658_splice | Splice Site (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2
- TAAR5 | c.625T>A p.F209I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- TAOK1 | c.2923G>T p.G975W | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TFDP3 | c.398T>G p.V133G | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TGFBI | c.1951C>A p.L651I | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.978); called by muse, mutect2
- TMC6 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- TRIM67 | c.1858G>T p.D620Y | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TRIML2 | c.1108G>T p.V370F | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TUBB2B | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); called by muse, mutect2
- TXNRD2 | c.1052T>C p.V351A | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- UNC5C | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- UNC80 | c.661C>G p.H221D | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- VCAN | c.10130C>T p.S3377L | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- VPS13D | c.12487A>T p.S4163C | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR62 | c.2034+1G>A p.X678_splice | Splice Site (SNP) | VAF 17/131 reads (13%) | called by muse, mutect2, varscan2
- ZIC3 | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZMYM2 | c.2374G>A p.D792N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF320 | c.761T>C p.F254S | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCB1 | c.1962T>A p.S654= | Silent (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- ADAM9 | c.2382A>G p.Q794= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as rs769730262; called by muse, mutect2
- AGBL1 | c.2739C>A p.G913= | Silent (SNP) | VAF 18/91 reads (20%) | called by muse, varscan2
- ANK2 | c.7116C>A p.S2372= | Silent (SNP) | VAF 36/99 reads (36%) | called by muse, mutect2, varscan2
- ARHGAP29 | c.2923C>T p.L975= | Silent (SNP) | VAF 25/99 reads (25%) | called by muse, mutect2, varscan2
- AUTS2 | c.2907G>C p.P969= | Silent (SNP) | VAF 20/186 reads (11%) | catalogued as COSV61430597; called by muse, mutect2, varscan2
- BRINP2 | c.42G>T p.P14= | Silent (SNP) | VAF 46/333 reads (14%) | catalogued as COSV64180828; called by muse, mutect2, varscan2
- BSN | c.7146G>A p.L2382= | Silent (SNP) | VAF 45/271 reads (17%) | catalogued as rs1457318582; called by muse, mutect2, varscan2
- CCDC39 | c.711G>A p.R237= | Silent (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- CYP2C18 | c.186C>T p.G62= | Silent (SNP) | VAF 20/216 reads (9%) | catalogued as rs143341184; called by muse, mutect2
- ELOF1 | c.240G>A p.A80= | Silent (SNP) | VAF 4/101 reads (4%) | catalogued as rs993484867, COSV99370741; called by muse, mutect2
- FAT3 | c.11655G>A p.L3885= | Silent (SNP) | VAF 19/101 reads (19%) | called by muse, mutect2, varscan2
- FCGBP | c.627C>T p.L209= | Silent (SNP) | VAF 8/159 reads (5%) | catalogued as rs138162470; called by muse, mutect2
- GABRA4 | c.798G>A p.P266= | Silent (SNP) | VAF 36/351 reads (10%) | catalogued as rs541280213, COSV51925155; called by muse, mutect2, varscan2
- GPR85 | c.243C>T p.V81= | Silent (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- HYDIN | c.10128C>A p.G3376= | Silent (SNP) | VAF 19/117 reads (16%) | called by muse, mutect2, varscan2
- IL12B | c.975G>T p.V325= | Silent (SNP) | VAF 54/200 reads (27%) | called by muse, mutect2, varscan2
- INSC | c.1320C>G p.T440= | Silent (SNP) | VAF 58/162 reads (36%) | called by muse, mutect2, varscan2
- KIF18B | c.39G>A p.R13= | Silent (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- KIF20A | c.2566C>A p.R856= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV67510651; called by muse, mutect2, varscan2
- KIF25 | c.480G>A p.A160= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as rs140066311; called by muse, mutect2, varscan2
- LPXN | c.1077G>A p.L359= | Silent (SNP) | VAF 36/214 reads (17%) | called by muse, mutect2, varscan2
- LRRCC1 | c.1653C>T p.L551= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- MPPED2 | c.735C>A p.P245= | Silent (SNP) | VAF 22/85 reads (26%) | called by muse, mutect2, varscan2
- MTMR2 | c.42G>A p.P14= | Silent (SNP) | VAF 50/266 reads (19%) | called by muse, mutect2, varscan2
- MYOM2 | c.4365C>T p.L1455= | Silent (SNP) | VAF 28/184 reads (15%) | catalogued as rs202224359, COSV50701986; called by muse, mutect2, varscan2
- MYOM3 | c.40C>A p.R14= | Silent (SNP) | VAF 47/276 reads (17%) | called by muse, mutect2, varscan2
- NFIA | c.1398T>A p.G466= | Silent (SNP) | VAF 59/379 reads (16%) | called by muse, mutect2, varscan2
- NIPAL3 | c.903G>T p.L301= | Silent (SNP) | VAF 31/138 reads (22%) | called by muse, mutect2, varscan2
- NUP205 | c.2559C>G p.L853= | Silent (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2, varscan2
- OR10A7 | c.285G>T p.V95= | Silent (SNP) | VAF 36/123 reads (29%) | catalogued as COSV100406605, COSV58279520; called by muse, mutect2, varscan2
- OR1A2 | c.810A>T p.A270= | Silent (SNP) | VAF 29/133 reads (22%) | called by muse, mutect2, varscan2
- PDIA4 | c.1401G>T p.G467= (on ENST00000286091 / NM_001371244.1; = p.G466= on NM_004911.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- PDLIM3 | c.570G>T p.T190= (on ENST00000284770 / NM_001257963.1; = p.T357= on NM_014476.6) | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV52977723, COSV52981552; called by muse, mutect2, varscan2
- PSG4 | c.862C>A p.R288= | Silent (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- PTPRN2 | c.1620C>A p.P540= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- R3HDM4 | c.309A>T p.P103= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, varscan2
- RC3H1 | c.996G>A p.Q332= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV51200824; called by muse, mutect2
- RCN1 | c.258G>A p.K86= | Silent (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- RHOH | c.450G>A p.E150= | Silent (SNP) | VAF 43/151 reads (28%) | catalogued as COSV67805879; called by muse, mutect2, varscan2
- RP1 | c.6273C>T p.I2091= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99078565; called by muse, mutect2, varscan2
- RYR2 | c.10920G>A p.L3640= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV100771314; called by muse, mutect2
- SACS | c.12462A>G p.P4154= | Silent (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- SAP130 | c.1182A>T p.T394= | Silent (SNP) | VAF 45/153 reads (29%) | called by muse, mutect2, varscan2
- SELENBP1 | c.141G>T p.V47= | Silent (SNP) | VAF 29/100 reads (29%) | called by muse, mutect2, varscan2
- SLC34A1 | c.1524G>T p.T508= | Silent (SNP) | VAF 23/97 reads (24%) | called by muse, mutect2, varscan2
- SLC6A2 | c.825C>T p.F275= | Silent (SNP) | VAF 33/177 reads (19%) | catalogued as rs746699464, COSV54923714; called by muse, mutect2, varscan2
- SPANXN5 | c.51T>C p.C17= | Silent (SNP) | VAF 26/155 reads (17%) | called by muse, mutect2, varscan2
- SPEG | c.798G>T p.R266= | Silent (SNP) | VAF 82/256 reads (32%) | called by muse, mutect2, varscan2
- STOX1 | c.2964C>T p.N988= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as rs745507419, COSV100057387; called by muse, mutect2
- TAS1R1 | c.1359C>A p.A453= | Silent (SNP) | VAF 30/143 reads (21%) | called by muse, mutect2, varscan2
- TBCB | c.33G>A p.V11= | Silent (SNP) | VAF 26/165 reads (16%) | catalogued as COSV52900595; called by muse, mutect2, varscan2
- TET3 | c.2634G>T p.T878= | Silent (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- TEX101 | c.669G>T p.G223= (on ENST00000598265 / NM_001130011.3; = p.G241= on NM_031451.4) | Silent (SNP) | VAF 44/174 reads (25%) | called by muse, mutect2, varscan2
- TIAL1 | c.159G>A p.V53= | Silent (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- TNFAIP2 | c.1518C>T p.F506= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as rs1328542531, COSV100281110; called by muse, mutect2
- TRIM67 | c.1857G>T p.R619= | Silent (SNP) | VAF 43/173 reads (25%) | called by muse, mutect2, varscan2
- USH2A | c.8016G>T p.L2672= | Silent (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- WFDC10B | c.12G>A p.Q4= | Silent (SNP) | VAF 22/142 reads (15%) | called by muse, mutect2, varscan2
- ZAN | c.6840C>T p.G2280= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as rs1399307962; called by muse, mutect2
- ZFR2 | c.186C>A p.P62= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs765140000; called by muse, mutect2, varscan2
- ZNF354B | c.603A>G p.L201= | Silent (SNP) | VAF 30/146 reads (21%) | called by muse, mutect2, varscan2
- ZNF595 | c.1275G>T p.T425= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs782376767, COSV59550105; called by muse, mutect2, varscan2
- ZNF793 | c.681C>T p.H227= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs371897623; called by muse, mutect2, varscan2
- FAM183BP | n.1151C>A | RNA (SNP) | VAF 29/165 reads (18%) | called by muse, mutect2, varscan2
- FAM27E5 | n.351G>T | RNA (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- NETO1 | c.29-343C>A | Intron (SNP) | VAF 49/215 reads (23%) | called by muse, mutect2, varscan2
- PNMA6A | chrX:153076390 C>A | 3'Flank (SNP) | VAF 27/167 reads (16%) | called by mutect2, varscan2
- SLC22A17 | n.560G>T | RNA (SNP) | VAF 38/221 reads (17%) | catalogued as rs1345756717; called by muse, mutect2, varscan2
